Gene-level copy-number profile of tumor specimen MP2PRT-PAPFWC-TMP1-A from MP2PRT case MP2PRT-PAPFWC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,716 days).
Specimen MP2PRT-PAPFWC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 001983b0-4286-462e-8e02-57d83dc6f49d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPFWC-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/db85984f-328e-4e86-980d-4e6ba9b50afc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 160; copy number 1: 3,022; copy number 2: 55,126; copy number 3: 73; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 160 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,297,785, 46 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37.
- chr2:90,121,786–90,173,414, 4 genes (within-gene range 0–2): IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11.
- chr2:113,432,600–113,436,042, 1 gene: AC016745.2.
- chr4:148,445,703–149,024,624, 7 genes (within-gene range 0–2): AC002460.2, ASS1P8, RNA5SP166, AC108935.1, ATP5MGP4, AC093648.1, AC002460.1.
- chr7:142,636,924–142,802,748, 35 genes: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr14:22,415,362–22,469,698, 11 genes (within-gene range 0–2): AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3.
- chr14:105,851,705–106,055,998, 46 genes (within-gene range 0–2): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6.
- chr14:106,088,122–106,108,464, 2 genes (within-gene range 0–1): IGHV3-64D, IGHV5-10-1.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr14:106,564,375–106,579,236, 3 genes (within-gene range 0–1): IGHVII-49-1, IGHV3-50, IGHV5-51.
- chr14:106,584,718–106,586,826, 2 genes (within-gene range 0–1): IGHVII-51-2, IGHV3-52.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:112,967–139,612, 3 genes, copy number 5 (within-gene range 2–5): AC069287.1, CICP23, LINC01001.

Autosomal genes at a single copy (total copy number 1): 678. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
